Somatic mutation profile of tumor specimen TCGA-2F-A9KR-01A (aliquot TCGA-2F-A9KR-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 59.8 years (21,848 days).
Specimen TCGA-2F-A9KR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c6216cb-15a0-4278-884c-3a5ff67dfc89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KR-10A (Blood Derived Normal), aliquot TCGA-2F-A9KR-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085aec79-f448-4278-a8a1-d6f68a324615

The open-access MAF lists 247 somatic variants for this specimen: 176 protein-altering or splice-affecting, 69 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 69, Nonsense Mutation 17, Splice Site 5, Frame Shift Del 2, Nonstop Mutation 2, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MPZ | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs797044845, CM013584, COSV60668161; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM3 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501123; called by muse, mutect2, varscan2
- ADAMTS8 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376637359; called by muse, mutect2, varscan2
- ANKFN1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs143082022; called by muse, mutect2
- ANKRD11 | c.7691A>G p.Y2564C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56359765; called by muse, mutect2, varscan2
- APRT | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs117335001, COSV51936831; called by muse, mutect2, varscan2
- ARCN1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50614798, COSV99873787; called by muse, mutect2, varscan2
- ART1 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 69/92 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51704151, COSV51706806; called by muse, mutect2, varscan2
- ASB15 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.38); catalogued as COSV51925523; called by muse, mutect2, varscan2
- ATP10D | c.2669-1G>T p.X890_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV56706745; called by muse, mutect2, varscan2
- AUTS2 | c.3260G>A p.R1087K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV61396809; called by muse, mutect2
- B4GALNT3 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV56751802; called by muse, mutect2, varscan2
- BAZ1B | c.4181C>T p.S1394F | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV59990593; called by muse, mutect2, varscan2
- BFSP1 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV64900497; called by muse, mutect2, varscan2
- BRIP1 | c.3376del p.E1126Kfs*24 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as COSV51998327; called by mutect2, pindel, varscan2
- C14orf39 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1292362525, COSV58781379; called by muse, mutect2, varscan2
- C9orf43 | c.808-2A>G p.X270_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as rs1259915358, COSV55912484; called by muse, mutect2, varscan2
- CAMTA2 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100772613; called by muse, mutect2, varscan2
- CCDC144A | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); catalogued as rs781022499, COSV60697902; called by muse, varscan2
- CCDC47 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV56722801; called by muse, mutect2, varscan2
- CCDC88A | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1180497053, COSV55060370, COSV55062862; called by muse, mutect2, varscan2
- CCHCR1 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV66183559; called by muse, mutect2, varscan2
- CDAN1 | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs375339408, CM023032; called by muse, varscan2
- CDK13 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51698988; called by muse, mutect2, varscan2
- CENPB | c.1792C>G p.Q598E | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV60146048; called by muse, mutect2, varscan2
- CENPL | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100616349; called by muse, mutect2
- CHMP3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs1177172351, COSV55685817; called by muse, mutect2, varscan2
- CKM | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs1167863722, COSV53463220; called by muse, mutect2, varscan2
- CLSTN1 | c.363G>T p.Q121H (on ENST00000377298 / NM_001009566.3; = p.Q111H on NM_014944.4) | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.613); catalogued as COSV63647779; called by muse, mutect2, varscan2
- COL3A1 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104394809, COSV58586318; called by muse, mutect2, varscan2
- COL9A2 | c.249+1G>A p.X83_splice | Splice Site (SNP) | VAF 56/156 reads (36%) | catalogued as rs1211057979, COSV65607420; called by muse, mutect2, varscan2
- CRP | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs775254047, COSV54813287; called by muse, mutect2, varscan2
- CYP4B1 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs931497782, COSV54723115, COSV99596965; called by muse, mutect2, varscan2
- DARS2 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 80/193 reads (41%) | catalogued as COSV99508711; called by muse, mutect2, varscan2
- DCC | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV59098531; called by muse, mutect2, varscan2
- DMXL2 | c.5257G>A p.V1753I | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV51844821; called by muse, mutect2, varscan2
- DONSON | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51677149; called by muse, mutect2, varscan2
- DSC1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as COSV57144137; called by muse, mutect2, varscan2
- DUOX2 | c.3632G>T p.R1211L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM152115, COSV66531770; called by muse, mutect2
- EIF4A2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 26/196 reads (13%) | catalogued as COSV99961220; called by muse, mutect2, varscan2
- EP300 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 81/132 reads (61%) | catalogued as COSV54329736, COSV99608957; called by muse, mutect2, varscan2
- EPB41L5 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55351326; called by muse, mutect2, varscan2
- EPHA5 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772452750, COSV56639254; called by muse, mutect2, varscan2
- EPPIN | c.401G>T p.*134Lext*23 | Nonstop Mutation (SNP) | VAF 44/99 reads (44%) | catalogued as COSV60549816; called by muse, mutect2, varscan2
- FAF1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65638038; called by muse, mutect2, varscan2
- FAM120C | c.2531G>T p.W844L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60258925; called by muse, mutect2, varscan2
- FAM171B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV59002700; called by muse, mutect2
- FCGR2A | c.432C>A p.H144Q (on ENST00000271450 / NM_001136219.3; = p.H143Q on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54838413; called by muse, mutect2, varscan2
- FIGN | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV60765638; called by muse, mutect2, varscan2
- FILIP1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV52727930; called by muse, mutect2
- FOXN1 | c.1376C>A p.S459* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs745708044, COSV99881296; called by muse, mutect2
- GALNT3 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs758500603, COSV67061671; called by muse, mutect2, varscan2
- GCN1 | c.6320G>C p.R2107P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56106843; called by mutect2, varscan2
- GCN1 | c.5014G>C p.E1672Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100325258, COSV56104561; called by muse, mutect2, varscan2
- GIGYF1 | c.2926G>C p.E976Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.979); catalogued as COSV51941094; called by muse, mutect2, varscan2
- GNL3L | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748605963, COSV60576068; called by muse, varscan2
- GNL3L | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs138960217, COSV60576075; called by muse, varscan2
- GNL3L | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV60576083; called by muse, varscan2
- GOLIM4 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 71/157 reads (45%) | catalogued as rs1428919297, COSV100463006; called by muse, mutect2, varscan2
- GPR50 | c.1419C>A p.N473K | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV54438624; called by muse, mutect2, varscan2
- GTF2F2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as rs1417116020, COSV61239276; called by muse, mutect2, varscan2
- H3C2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as rs1332600888, COSV52518397, COSV52518528; called by muse, mutect2, varscan2
- HEATR5B | c.5875C>T p.L1959F | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV51852061; called by muse, mutect2, varscan2
- HENMT1 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as rs748146308, COSV100898661; called by muse, mutect2, varscan2
- HEY2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV64239328; called by muse, mutect2, varscan2
- HIPK4 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs1473930178, COSV52520602, COSV99397042; called by muse, mutect2, varscan2
- IGSF1 | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100812396, COSV63836194; called by muse, mutect2, varscan2
- IL12RB2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772560362, COSV52022909; called by muse, mutect2, varscan2
- IMPDH2 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58244780; called by muse, mutect2, varscan2
- IPO8 | c.2885C>T p.T962I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as COSV56241080; called by muse, mutect2, varscan2
- KANSL1 | c.2489C>G p.S830* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99294506; called by muse, mutect2, varscan2
- KBTBD3 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV73241358; called by muse, mutect2, varscan2
- KDM4C | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV67185934; called by muse, mutect2, varscan2
- KIF21A | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62770421, COSV62775268; called by muse, mutect2, varscan2
- KLHL6 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58065975; called by muse, mutect2
- KRT35 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1381140397, COSV55842865, COSV99877850; called by muse, mutect2, varscan2
- LAMP3 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV55614508; called by muse, mutect2, varscan2
- LARP4B | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 30/43 reads (70%) | catalogued as COSV60221422; called by muse, mutect2, varscan2
- LGR5 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57004415, COSV57007879; called by muse, mutect2, varscan2
- LIN7A | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV54020645; called by muse, mutect2, varscan2
- LONP1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV62260771, COSV62261445; called by muse, mutect2, varscan2
- LRPPRC | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.078); catalogued as rs776095587, COSV53237413; called by muse, mutect2, varscan2
- LRRC4B | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100975914; called by muse, mutect2
- LRRC66 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 60/148 reads (41%) | catalogued as COSV100602962; called by muse, mutect2, varscan2
- LRRIQ1 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV67829645; called by muse, mutect2, varscan2
- LRRTM3 | c.1631C>A p.S544Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.302); catalogued as COSV63664418; called by muse, mutect2, varscan2
- MAP4K1 | c.1440G>C p.K480N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.149); catalogued as rs1418756111, COSV101204235; called by muse, mutect2, varscan2
- MDN1 | c.4013C>A p.S1338Y | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV65520704; called by muse, mutect2, varscan2
- MEGF8 | c.1544C>G p.S515* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99236349; called by muse, mutect2, varscan2
- MFSD4A | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65656370, COSV65656613; called by muse, mutect2, varscan2
- MMP27 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs369662296; called by muse, mutect2, varscan2
- MRE11 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs754078280, COSV60576116; ClinVar: uncertain significance; called by muse, varscan2
- MSANTD3 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV100614693; called by muse, mutect2
- MYBPC1 | c.317C>A p.A106D (on ENST00000550270 / NM_206820.2; = p.A131D on NM_002465.4) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as COSV62252555; called by muse, mutect2, varscan2
- MYBPC1 | c.376G>A p.E126K (on ENST00000550270 / NM_206820.2; = p.E151K on NM_002465.4) | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746663966, COSV62252563, COSV62252686; called by muse, mutect2, varscan2
- MYH6 | c.3321G>C p.Q1107H | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100676864, COSV62449714; called by muse, mutect2
- NAGA | c.1236A>T p.*412Cext*13 | Nonstop Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as rs1303189391, COSV101124150; called by muse, mutect2, varscan2
- NAV2 | c.7078G>A p.D2360N (on ENST00000396087 / NM_001244963.2; = p.D2301N on NM_145117.5) | Missense Mutation (SNP) | VAF 142/180 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60658698; called by muse, mutect2, varscan2
- NCK2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1264859840, COSV51890730; called by muse, mutect2, varscan2
- NELFCD | c.1544G>A p.R515Q (on ENST00000602795; = p.R497Q on NM_198976.4) | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV53883053; called by muse, mutect2, varscan2
- NELL1 | c.1427-1G>A p.X476_splice | Splice Site (SNP) | VAF 15/24 reads (63%) | catalogued as COSV54254585, COSV54274882; called by muse, mutect2, varscan2
- NLGN3 | c.1295C>G p.S432C (on ENST00000358741 / NM_181303.2; = p.S412C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV62441871, COSV62442750; called by muse, mutect2, varscan2
- NYX | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs372496317, COSV61180676; called by muse, mutect2, varscan2
- OPCML | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100101405; called by muse, varscan2
- OR4C13 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV73648726; called by muse, mutect2, varscan2
- OR5R1 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV56572132, COSV56572892; called by muse, mutect2, varscan2
- OTOGL | c.1384T>C p.C462R (on ENST00000547103; = p.C453R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759814009, COSV72006493; called by muse, mutect2, varscan2
- PCDHB12 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782043522, COSV53395652; called by muse, mutect2, varscan2
- PCDHB12 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); catalogued as rs1554286996, COSV53394760; called by muse, mutect2, varscan2
- PHETA1 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs769647578, COSV100825359; called by muse, varscan2
- PIK3CA | c.3034G>C p.E1012Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55907590, COSV55914417; called by muse, mutect2, varscan2
- PKLR | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV61360849; called by muse, mutect2, varscan2
- POLM | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV54242340, COSV54243788; called by muse, mutect2, varscan2
- POLR1D | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1209845490, COSV68799526, COSV68799985; called by muse, mutect2
- PRC1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62695048; called by muse, mutect2
- PRKAB1 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554944; called by muse, mutect2, varscan2
- PROZ | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1404814131, COSV61439227; called by muse, mutect2, varscan2
- PUS10 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV57451955; called by muse, mutect2, varscan2
- RACGAP1 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.779); catalogued as COSV100407886, COSV56699117; called by muse, mutect2, varscan2
- RARS1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV51563113; called by muse, mutect2, varscan2
- REV1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV51483831; called by muse, mutect2, varscan2
- REXO1 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV50076935; called by muse, mutect2, varscan2
- RFXAP | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as rs1409045927, COSV55225915; called by muse, mutect2
- RPS4X | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV60181641; called by muse, mutect2, varscan2
- RSRC2 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59203979; called by muse, mutect2
- RTL4 | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61206268; called by muse, mutect2, varscan2
- RYR2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs754259295, COSV63678919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV66785802; called by muse, mutect2, varscan2
- SAMD9 | c.3370G>A p.G1124S | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66074668; called by muse, mutect2, varscan2
- SATB1 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV100113209, COSV58668775; called by muse, mutect2, varscan2
- SCAF4 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54586313; called by muse, mutect2, varscan2
- SETD1A | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52687011; called by muse, mutect2, varscan2
- SIGIRR | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs774838659, COSV58986870; called by muse, varscan2
- SLC39A8 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV63222454; called by muse, mutect2
- SMAD7 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV50989256; called by muse, mutect2, varscan2
- SMG1 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV67170829; called by muse, mutect2, varscan2
- SPTBN2 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59450782; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | PolyPhen benign (0.007); catalogued as COSV60329567; called by muse, mutect2, varscan2
- STAG2 | c.2097-1G>A p.X699_splice | Splice Site (SNP) | VAF 36/80 reads (45%) | catalogued as COSV54354162, COSV54372409; called by mutect2, varscan2
- STOML3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs374030322, COSV65510505, COSV65511300; called by muse, mutect2, varscan2
- SYMPK | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV55571262; called by muse, mutect2, varscan2
- TASOR2 | c.2552C>G p.S851C | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV60167064; called by muse, mutect2, varscan2
- TATDN1 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV52679084; called by muse, mutect2, varscan2
- TBX15 | c.1504C>T p.Q502* (on ENST00000369429 / NM_001330677.2; = p.Q396* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as rs1321909902, COSV99254166; called by muse, mutect2, varscan2
- THOC2 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV55544688; called by muse, mutect2, varscan2
- TMCO4 | c.1381A>T p.R461W | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53871988; called by muse, mutect2, varscan2
- TMX2 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 84/104 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53554056; called by muse, mutect2, varscan2
- TOP3B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64117025; called by muse, mutect2, varscan2
- TOX | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100812740; called by muse, mutect2
- TRAK1 | c.562G>A p.E188K (on ENST00000327628 / NM_001349247.2; = p.E130K on NM_014965.5) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV58257873; called by muse, mutect2, varscan2
- TRERF1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100550733; called by muse, mutect2
- TTLL7 | c.1037G>T p.W346L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs1215670228, COSV53083681; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54436622; called by muse, mutect2, varscan2
- UMODL1 | c.2695G>A p.D899N (on ENST00000408910 / NM_001004416.2; = p.D1027N on NM_173568.3) | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1446268427, COSV68569683; called by muse, mutect2, varscan2
- USP8 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1396824151, COSV56163873; called by muse, mutect2, varscan2
- ZBBX | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV56787771; called by muse, mutect2, varscan2
- ZCCHC13 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV59866190; called by muse, mutect2, varscan2
- ZFAND6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550628286, COSV55711581; called by muse, mutect2, varscan2
- ZFHX3 | c.10507C>T p.H3503Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV51715975, COSV99212844; called by muse, varscan2
- ZFHX4 | c.4616G>A p.R1539H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs981659626, COSV50703705; called by muse, mutect2, varscan2
- ZIM3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV54142024, COSV54143836, COSV54146692; called by muse, mutect2, varscan2
- ZNF16 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV52763395; called by muse, mutect2, varscan2
- ZNF174 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51902505; called by muse, mutect2, varscan2
- ZNF263 | c.1484G>T p.C495F | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54596216; called by muse, mutect2, varscan2
- ZNF362 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs755697341, COSV65031366; called by muse, mutect2, varscan2
- ZNF526 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56629514; called by muse, mutect2, varscan2
- ZNF667 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52633376; called by muse, mutect2, varscan2
- ZNF781 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV62201151; called by muse, mutect2
- ZNF835 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV73379217; called by muse, mutect2, varscan2
- ZSCAN20 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63682390; called by muse, mutect2, varscan2
- GAS2L1 | c.814_836del p.D272Cfs*27 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel
- HOXD1 | c.704_724del p.N235_L241del | In Frame Del (DEL) | VAF 16/191 reads (8%) | called by mutect2, pindel
- HP1BP3 | c.1574dup p.K526Efs*76 | Frame Shift Ins (INS) | VAF 19/122 reads (16%) | called by mutect2, pindel, varscan2
- TRBV20-1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC8 | c.3361C>T p.L1121= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV56849417; called by muse, mutect2, varscan2
- ABHD12 | c.978C>T p.L326= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs778892788, COSV59285274, COSV59286032, COSV59286250; called by muse, mutect2, varscan2
- ACAD9 | c.1743C>T p.F581= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV58307275; called by muse, mutect2, varscan2
- AHNAK2 | c.8280G>A p.L2760= | Silent (SNP) | VAF 132/203 reads (65%) | catalogued as rs754780542, COSV60913833; called by muse, mutect2, varscan2
- AMTN | c.489C>A p.A163= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV59488814; called by muse, mutect2, varscan2
- ANGPT1 | c.558G>A p.K186= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs1340847685, COSV52438045; called by muse, mutect2, varscan2
- ASTN1 | c.2904C>G p.P968= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV62495688; called by muse, mutect2
- ATP13A5 | c.1446C>T p.L482= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs1309813514, COSV60868536; called by muse, mutect2, varscan2
- CDH1 | c.1125C>T p.F375= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV55731311; called by muse, mutect2, varscan2
- CELSR1 | c.1317C>A p.L439= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53088405; called by muse, mutect2, varscan2
- CRMP1 | c.1530C>G p.P510= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV61479683; called by muse, mutect2, varscan2
- CRP | c.246C>G p.L82= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV54813277; called by muse, mutect2, varscan2
- CRTC2 | c.75G>A p.K25= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV57841160; called by muse, mutect2, varscan2
- CYBC1 | c.240G>A p.L80= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60063714; called by muse, mutect2, varscan2
- DCST2 | c.1302C>T p.D434= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV55051300; called by muse, mutect2
- DISP1 | c.3921G>A p.Q1307= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs749083760, COSV52657899, COSV52660492; called by muse, mutect2, varscan2
- ECM1 | c.630C>G p.L210= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as COSV60872754; called by muse, mutect2, varscan2
- ERAL1 | c.1287C>T p.I429= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV54739756; called by muse, mutect2
- ESR2 | c.1290G>C p.L430= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as rs768749310, COSV50830154; called by muse, mutect2, varscan2
- FAT2 | c.4941C>T p.I1647= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs775817164, COSV55818334; called by muse, mutect2, varscan2
- GON4L | c.4404C>T p.L1468= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV55192380; called by muse, mutect2, varscan2
- GPR107 | c.1620T>C p.V540= (on ENST00000372406 / NM_001136557.2; = p.V492= on NM_020960.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV61278901; called by muse, mutect2
- GPR52 | c.474G>A p.L158= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as COSV52290865; called by muse, mutect2, varscan2
- GPR75 | c.1455C>T p.I485= | Silent (SNP) | VAF 31/232 reads (13%) | catalogued as COSV61826594; called by muse, mutect2, varscan2
- GUCA1C | c.519C>T p.F173= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1028693252, COSV53756567; called by muse, mutect2, varscan2
- H2BC15 | c.213C>T p.F71= | Silent (SNP) | VAF 118/263 reads (45%) | catalogued as rs144837583, COSV57585493; called by muse, mutect2, varscan2
- HS6ST3 | c.54C>T p.F18= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs1337031941, COSV65007181; called by muse, mutect2, varscan2
- IL27RA | c.720G>T p.G240= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV54600281; called by muse, mutect2, varscan2
- IL4I1 | c.1611C>T p.P537= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV55578223; called by muse, mutect2, varscan2
- KCNG3 | c.255C>T p.F85= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1285138887, COSV60148332; called by muse, mutect2
- KCNH2 | c.3309C>T p.L1103= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV51138652; called by muse, mutect2, varscan2
- KIAA1217 | c.444G>A p.L148= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as rs531305542, COSV64604566; called by muse, mutect2, varscan2
- LAMA5 | c.3621C>T p.I1207= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs750388907, COSV53362177; called by muse, mutect2, varscan2
- LILRA6 | c.93C>G p.L31= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs765893465, COSV54433964; called by muse, varscan2
- LILRB3 | c.93C>G p.L31= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99557732; called by muse, mutect2, varscan2
- MARCHF10 | c.2196G>A p.Q732= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV60886653; called by muse, mutect2, varscan2
- NEB | c.10632G>A p.P3544= | Silent (SNP) | VAF 49/282 reads (17%) | catalogued as rs200043736; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NIPBL | c.3147A>G p.K1049= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV56949621; called by muse, mutect2, varscan2
- NUMBL | c.945G>A p.K315= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53286334, COSV99424927; called by muse, mutect2, varscan2
- OR5F1 | c.735G>A p.L245= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1422608497, COSV53546199; called by muse, mutect2, varscan2
- OTUD6A | c.675G>A p.L225= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV57973141; called by muse, mutect2, varscan2
- PCDHB6 | c.390G>A p.P130= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as COSV50694533; called by muse, mutect2, varscan2
- PCYOX1 | c.528C>T p.F176= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV52476194; called by muse, mutect2, varscan2
- PGAP6 | c.1659C>T p.L553= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs919087989, COSV51738942; called by muse, mutect2, varscan2
- PPP2R2B | c.43C>T p.L15= (on ENST00000394409; = p.L81= on NM_181674.2) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV60762968; called by muse, mutect2, varscan2
- PRKCG | c.249C>T p.F83= | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as rs755321480, COSV99669009; called by muse, mutect2, varscan2
- RECQL4 | c.3021C>G p.L1007= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100020573; called by muse, mutect2, varscan2
- RIMBP2 | c.2178G>A p.L726= | Silent (SNP) | VAF 74/121 reads (61%) | catalogued as COSV55470533; called by muse, mutect2, varscan2
- SIGLEC12 | c.1497C>T p.F499= (on ENST00000291707 / NM_053003.4; = p.F381= on NM_033329.2) | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs774896262, COSV52460967; called by muse, mutect2, varscan2
- SIPA1L3 | c.3933C>T p.I1311= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs748637025, COSV55912754; called by muse, mutect2, varscan2
- SLC16A7 | c.342C>T p.L114= | Silent (SNP) | VAF 72/191 reads (38%) | catalogued as COSV53893830, COSV99676760; called by muse, varscan2
- SNF8 | c.354G>A p.L118= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV51726411; called by muse, mutect2, varscan2
- SPATA1 | c.1113C>T p.I371= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV55362065; called by muse, mutect2, varscan2
- SPATA20 | c.1902G>A p.L634= (on ENST00000356488 / NM_001258372.1; = p.L650= on NM_022827.4) | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as COSV50066388; called by muse, mutect2, varscan2
- SYT10 | c.270T>A p.T90= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV57339678; called by muse, mutect2, varscan2
- TBC1D9 | c.3549C>T p.I1183= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1049754143, COSV71307322; called by muse, mutect2, varscan2
- TECRL | c.150A>G p.P50= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs1309421868, COSV67086779; called by muse, mutect2, varscan2
- TF | c.723G>A p.Q241= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as rs777168746, COSV53919828; called by muse, mutect2, varscan2
- TIGD7 | c.201G>A p.E67= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as rs1467704239, COSV51915877; called by muse, mutect2, varscan2
- TIGD7 | c.15G>A p.G5= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV51915889; called by muse, mutect2, varscan2
- TMED4 | c.624C>T p.L208= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV56941802; called by muse, mutect2, varscan2
- TRIM13 | c.1140C>T p.F380= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV53949048; called by muse, mutect2, varscan2
- VWA1 | c.636G>A p.A212= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs781470522, COSV58599802; called by muse, mutect2, varscan2
- WDR64 | c.1770G>T p.V590= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as COSV63795052; called by muse, mutect2, varscan2
- WDR72 | c.2262T>C p.D754= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV64745601; called by muse, mutect2, varscan2
- XPR1 | c.75C>T p.F25= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as COSV62556052; called by muse, mutect2, varscan2
- ZCCHC2 | c.1254G>A p.L418= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV54037419, COSV99502491; called by muse, mutect2, varscan2
- ZNF699 | c.558C>G p.L186= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV58025440; called by muse, mutect2, varscan2
- ZNF780B | c.2040T>C p.R680= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as COSV55463638; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823212 C>A | 5'Flank (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- PARP10 | chr8:143975354 C>A | 3'Flank (SNP) | VAF 12/55 reads (22%) | catalogued as rs1554745732, COSV57297252; called by muse, mutect2, varscan2
